Somatic mutation profile of tumor specimen TCGA-CM-6679-01A (aliquot TCGA-CM-6679-01A-11D-1835-10) from TCGA case TCGA-CM-6679, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 58.9 years (21,519 days).
Specimen TCGA-CM-6679-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88f70db0-7b94-46b8-ae15-6ba0dcab6702.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6679-10A (Blood Derived Normal), aliquot TCGA-CM-6679-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b79743a8-1674-4e6f-8ee7-77e32edb30a9

The open-access MAF lists 69 somatic variants for this specimen: 50 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 16, Nonsense Mutation 2, 3'UTR 2, Splice Site 2, Frame Shift Del 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1958+1G>A p.X653_splice | Splice Site (SNP) | VAF 15/42 reads (36%) | catalogued as rs1114167569, CD014920, CS011023, CS011024, HS080016, COSV57330281, COSV57355367; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.3245G>A p.R1082H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761945307, COSV66065412; called by muse, mutect2, varscan2
- ABCC12 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs146796778; called by muse, mutect2, varscan2
- ADAMTS20 | c.3751C>T p.R1251C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs777466280, COSV67131235, COSV67139700; called by muse, mutect2, varscan2
- BACE2 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.127); catalogued as rs559873325, COSV57739540; called by muse, mutect2
- CCSER2 | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99825965; called by mutect2, varscan2
- CHD7 | c.3674A>G p.N1225S | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV71110208; called by muse, mutect2, varscan2
- COL2A1 | c.3827G>A p.R1276H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs142168567, COSV61530652; called by muse, mutect2, varscan2
- COL6A2 | c.2591C>T p.T864M | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.07); PolyPhen benign (0.431); catalogued as rs200488881; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSNK1D | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs751091452, COSV53924388; called by muse, mutect2, varscan2
- DDX19A | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs779504912, COSV56359641; called by muse, mutect2, varscan2
- DENND4C | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100991326; called by muse, mutect2, varscan2
- DSC3 | c.373A>T p.T125S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100844605; called by muse, mutect2, varscan2
- ETS1 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs759420818, COSV60093452; called by muse, mutect2, varscan2
- FOXN2 | c.62T>A p.I21N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV61318027; called by muse, mutect2, varscan2
- FREM2 | c.7096A>G p.M2366V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99748823; called by muse, mutect2, varscan2
- GPLD1 | c.2254G>T p.G752W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57756967; called by muse, mutect2, varscan2
- HECTD4 | c.5393A>G p.N1798S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.995); catalogued as rs1474687359; called by muse, mutect2
- HOXB3 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV61144708; called by muse, varscan2
- IGF2BP3 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs145484983; called by mutect2, varscan2
- IGLV1-44 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 18/108 reads (17%) | catalogued as rs773836767; called by muse, mutect2, varscan2
- JHY | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146523567; called by muse, mutect2, varscan2
- KCNK1 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1208127015, COSV64038105; called by muse, mutect2, varscan2
- KIAA0408 | c.317A>T p.K106I | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.525); catalogued as COSV64106513; called by muse, mutect2, varscan2
- KIR2DL1 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.089); catalogued as rs748379865, COSV52417259; called by muse, mutect2, varscan2
- LATS2 | c.1738G>A p.V580I | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV101231572; called by muse, mutect2
- MAL | c.127T>A p.S43T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV59431407; called by muse, mutect2, varscan2
- MTCL1 | c.2162C>T p.A721V (on ENST00000306329 / NM_001378206.1; = p.A361V on NM_015210.4) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747997287, COSV100094575; called by muse, mutect2, varscan2
- NPBWR2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs370307704; called by muse, mutect2
- OR11A1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs779742908, COSV65820931, COSV65821071; called by muse, mutect2, varscan2
- OR7G3 | c.794C>T p.T265I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.25); catalogued as rs746836067, COSV100555678; called by mutect2, varscan2
- P2RY8 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs762114324, COSV67177276; called by muse, mutect2, varscan2
- PGLYRP2 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52992630; called by muse, mutect2, varscan2
- PRM3 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as rs376400498; called by muse, mutect2, varscan2
- RSAD1 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs755722994, COSV51955621; called by muse, mutect2, varscan2
- SBF2 | c.4644G>A p.M1548I | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV99814266; called by muse, mutect2
- SDK2 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as rs139146725, COSV66182353; called by muse, mutect2, varscan2
- SP140 | c.1058-1G>A p.X353_splice | Splice Site (SNP) | VAF 17/53 reads (32%) | catalogued as rs369421172; called by muse, mutect2, varscan2
- ST6GAL2 | c.1187A>C p.Q396P | Missense Mutation (SNP) | VAF 11/29 reads (38%) | PolyPhen possibly damaging (0.734); catalogued as COSV100699604; called by muse, mutect2, varscan2
- SYNE1 | c.13852C>T p.L4618F (on ENST00000367255 / NM_182961.4; = p.L4547F on NM_033071.3) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99564758; called by muse, mutect2, varscan2
- TAS1R3 | c.1692G>A p.W564* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as rs762273197, COSV100229833, COSV59563348; called by muse, mutect2, varscan2
- TIAM1 | c.4289C>T p.P1430L | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs749306505, COSV54550346; called by muse, mutect2, varscan2
- TP53 | c.592dup p.E198Gfs*11 | Frame Shift Ins (INS) | VAF 17/48 reads (35%) | catalogued as COSV104370759; called by mutect2, pindel, varscan2
- TPPP2 | c.479A>G p.K160R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV100409565; called by muse, mutect2
- TTN | c.57418G>C p.V19140L (on ENST00000591111; = p.V11716L on NM_003319.4) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | PolyPhen probably damaging (0.99); catalogued as COSV60049204; called by muse, mutect2, varscan2
- TTN | c.5254C>T p.R1752C (on ENST00000591111; = p.R1706C on NM_003319.4) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | PolyPhen probably damaging (0.998); catalogued as rs1259833413, COSV100600808, COSV59989131; called by muse, mutect2, varscan2
- ZNF699 | c.1879C>A p.P627T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV58025588; called by muse, mutect2, varscan2
- ZPBP2 | c.757T>C p.Y253H (on ENST00000348931 / NM_199321.3; = p.Y231H on NM_198844.3) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100818518; called by muse, varscan2
- MED13L | c.5306A>C p.K1769T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCNN1B | c.1312_1315del p.E438Pfs*17 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- CPA4 | c.292T>C p.L98= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99745034; called by muse, mutect2, varscan2
- DIPK2A | c.765G>A p.A255= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as rs371349121; called by muse, mutect2, varscan2
- FLG | c.1227C>T p.V409= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100911595; called by muse, mutect2, varscan2
- FUCA1 | c.219C>T p.G73= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs1227826989, COSV100991417; called by muse, mutect2
- GRIK3 | c.2235C>T p.Y745= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs763045219, COSV66138020; called by muse, mutect2, varscan2
- MAML2 | c.3147C>T p.L1049= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV73263395; called by muse, mutect2, varscan2
- NRXN1 | c.798G>A p.A266= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs201027928; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- OR4K17 | c.660G>A p.L220= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs1215043581, COSV59648995; called by muse, mutect2, varscan2
- PTPN5 | c.906G>A p.A302= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs781071029, COSV62125748; called by muse, mutect2, varscan2
- SLC25A20 | c.207G>A p.T69= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs1397470610, COSV59802852; called by muse, mutect2
- SPAG17 | c.4230A>G p.R1410= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as COSV100309146; called by muse, mutect2
- STAMBP | c.1092C>T p.A364= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV59897377; called by muse, mutect2, varscan2
- STAU2 | c.795G>T p.A265= (on ENST00000524300 / NM_001164380.2; = p.A233= on NM_014393.2) | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs368673903, COSV100869106; called by muse, mutect2, varscan2
- SYNE1 | c.23974C>T p.L7992= (on ENST00000367255 / NM_182961.4; = p.L7921= on NM_033071.3) | Silent (SNP) | VAF 44/100 reads (44%) | catalogued as COSV54930503, COSV54978057; called by muse, mutect2, varscan2
- ZBED4 | c.987G>A p.R329= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV99351219; called by muse, mutect2, varscan2
- ZNF318 | c.5142A>T p.P1714= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV58932449; called by muse, mutect2, varscan2
- ATAD3C | c.*143C>T | 3'UTR (SNP) | VAF 12/27 reads (44%) | catalogued as rs759185597, COSV58022418; called by muse, mutect2, varscan2
- SLC26A9 | c.*316G>A | 3'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- TLCD2 | chr17:1713945 C>G | 5'Flank (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2
